Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A7DP, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A7DP-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: The tumor infiltrate the surrounding tissues

Microscopic Description: Adenocarcinoma, G2,

Diagnosis Details: There are metastases in surrounding tissues

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Exploratory surgery

Tumor site: Esophagus

Tumor size: Not specified

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: There are metastases in surrounding tissues. Tumor involves distal 3rd of esophagus.

Comments: None

ICD-O-3
Adenocarcinoma NOS
8140/3
Site Esophagus, distal third
C15.5
JW 9/4/13

HPV A Discrepancy		✓
Pathologic Malignancy History		✓
Reviewed (initials)	Kml	

Source: NCI Genomic Data Commons file 15229dab-0ab6-44af-ab81-2c4917fe4e47 (TCGA-IG-A7DP.563EF32E-3F03-41D9-AC7E-8FC8E82BDD35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).